Somatic mutation profile of tumor specimen TCGA-21-5782-01A (aliquot TCGA-21-5782-01A-01D-1632-08) from TCGA case TCGA-21-5782, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 68.4 years (24,969 days).
Specimen TCGA-21-5782-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b8631e2-dcfb-4c3a-a10b-6ae438d50729.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-5782-10A (Blood Derived Normal), aliquot TCGA-21-5782-10A-01D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d7cab68-1a99-4921-a01b-677cdd93f8ef

The open-access MAF lists 433 somatic variants for this specimen: 327 protein-altering or splice-affecting, 91 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 273, Silent 91, Nonsense Mutation 28, Frame Shift Del 14, Splice Site 8, RNA 6, Intron 3, 3'UTR 3, In Frame Del 3, 5'UTR 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.7500del p.R2500Sfs*24 | Frame Shift Del (DEL) | VAF 30/109 reads (28%) | catalogued as rs1566241962; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 65/127 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.584T>G p.I195S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABI1 | c.254G>A p.R85K | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV61018964; called by muse, mutect2, varscan2
- AC100868.1 | c.1394G>A p.R465K | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.124); catalogued as COSV51847287; called by muse, mutect2
- ADAMTS12 | c.4479G>C p.K1493N | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as COSV61258479; called by muse, mutect2, varscan2
- ADAMTS16 | c.1553G>T p.C518F | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57000083; called by muse, mutect2, varscan2
- ADAMTS16 | c.2323C>A p.R775S | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.49); catalogued as COSV57000103; called by muse, mutect2, varscan2
- ADAMTS20 | c.371C>A p.S124* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV67125673, COSV67136081, COSV67136513; called by muse, mutect2, varscan2
- ADGRG4 | c.2113C>A p.L705M | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.276); catalogued as COSV54962792; called by muse, mutect2, varscan2
- ADGRG4 | c.9131C>A p.S3044* | Nonsense Mutation (SNP) | VAF 43/190 reads (23%) | catalogued as COSV54962807; called by muse, mutect2, varscan2
- ADORA2A | c.596G>T p.R199L | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV58379837; called by muse, mutect2, varscan2
- AHNAK | c.16811C>T p.S5604F | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV57223628, COSV57226622; called by muse, mutect2, varscan2
- AHNAK2 | c.10846G>C p.D3616H | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV60923857; called by muse, mutect2, varscan2
- AKAP8 | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs779457121, COSV54103808; called by muse, mutect2, varscan2
- ALLC | c.187G>T p.V63F | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV52997014; called by muse, mutect2, varscan2
- ALX4 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV61327986; called by muse, mutect2, varscan2
- ANAPC4 | c.2081A>G p.D694G | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV59545480; called by muse, mutect2, varscan2
- AOX1 | c.3242C>T p.P1081L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53496731; called by muse, mutect2, varscan2
- AP4B1 | c.820C>T p.L274F | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.615); catalogued as rs563341771, COSV56726211; called by muse, mutect2, varscan2
- AQP2 | c.696G>C p.E232D | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV52231257; called by muse, mutect2
- ARHGAP6 | c.2065G>T p.A689S | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0.012); catalogued as rs769180225, COSV57299891; called by muse, mutect2, varscan2
- ARMC5 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750797663, COSV51657791; called by muse, mutect2, varscan2
- ASB12 | c.355C>A p.L119M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV62857387; called by muse, mutect2, varscan2
- ASPH | c.1196G>T p.R399L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.047); catalogued as COSV65246204; called by muse, mutect2, varscan2
- ASTN2 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV57747924; called by muse, mutect2, varscan2
- ATP12A | c.2042C>T p.T681I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as COSV54520067; called by muse, mutect2, varscan2
- ATP2B2 | c.1438G>T p.G480C (on ENST00000352432; = p.G446C on NM_001683.5) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59503764; called by muse, mutect2, varscan2
- ATP5F1C | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59622480; called by muse, mutect2
- AVPR1A | c.86G>T p.S29I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV54547535; called by muse, mutect2
- BCAS1 | c.1634G>T p.R545I | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs772677080, COSV65088257; called by muse, mutect2, varscan2
- BICD1 | c.1005+1G>A p.X335_splice | Splice Site (SNP) | VAF 8/34 reads (24%) | catalogued as COSV55684551; called by muse, mutect2, varscan2
- BPHL | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66744225; called by muse, mutect2, varscan2
- BRCA1 | c.959G>C p.R320T | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58795787; called by muse, mutect2, varscan2
- BRWD1 | c.267G>T p.L89F | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58123373; called by muse, mutect2, varscan2
- BTK | c.103C>A p.H35N | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV58122455; called by muse, mutect2, varscan2
- C11orf54 | c.879C>A p.Y293* (on ENST00000331239; = p.Y243* on NM_014039.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/73 reads (18%) | catalogued as COSV58681550; called by muse, mutect2, varscan2
- CAMTA1 | c.5006A>G p.K1669R | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV50012789; called by muse, mutect2, varscan2
- CARMIL1 | c.2745G>A p.M915I | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.21); PolyPhen benign (0.391); catalogued as COSV61521514; called by muse, mutect2
- CASD1 | c.569C>A p.S190Y | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as COSV51974353; called by muse, mutect2
- CBLN4 | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.268); catalogued as COSV50353769; called by muse, mutect2, varscan2
- CCDC120 | c.577C>A p.Q193K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.678); catalogued as COSV64515591; called by muse, mutect2
- CCDC9B | c.919G>C p.D307H | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV66875849; called by muse, mutect2, varscan2
- CCND3 | c.782C>G p.T261S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV57829171; called by muse, mutect2
- CD1A | c.631G>A p.G211S | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.732); catalogued as rs1207209067, COSV56863339; called by muse, mutect2, varscan2
- CD1A | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV56863352; called by muse, mutect2, varscan2
- CD38 | c.659G>A p.S220N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56891997, COSV99883052; called by muse, mutect2, varscan2
- CEACAM8 | c.895T>A p.C299S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54991351; called by muse, mutect2, varscan2
- CELSR2 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54776744; called by muse, mutect2, varscan2
- CEP164 | c.954G>C p.K318N | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as COSV54044328; called by muse, mutect2, varscan2
- CES2 | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV57697450; called by muse, mutect2, varscan2
- CFAP47 | c.4318G>T p.D1440Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV57975517, COSV57976132; called by muse, mutect2, varscan2
- CFHR5 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV56825584; called by muse, mutect2, varscan2
- CGA | c.92G>A p.C31Y | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63644042; called by muse, mutect2, varscan2
- CHD2 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as COSV59121749; called by muse, mutect2, varscan2
- CHRDL1 | c.427-2A>T p.X143_splice (on ENST00000372045; = p.X149_splice on NM_145234.4) | Splice Site (SNP) | VAF 13/45 reads (29%) | catalogued as COSV54327286; called by muse, mutect2, varscan2
- CLSPN | c.3586G>T p.E1196* | Nonsense Mutation (SNP) | VAF 27/67 reads (40%) | catalogued as COSV52054973; called by muse, mutect2, varscan2
- CNTN5 | c.2269G>T p.G757* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV54337629; called by muse, mutect2, varscan2
- COL2A1 | c.2881G>A p.D961N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV61532662; called by muse, mutect2, varscan2
- COL6A2 | c.57G>C p.Q19H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV56011939; called by muse, varscan2
- COL6A2 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV56011960; called by muse, varscan2
- COPS7B | c.396C>G p.I132M | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV62601473; called by muse, mutect2, varscan2
- CPSF7 | c.40G>C p.E14Q (on ENST00000394888 / NM_001136040.4; = p.E57Q on NM_024811.4) | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.983); catalogued as COSV100073961, COSV100073992, COSV57099852; called by muse, mutect2, varscan2
- CRMP1 | c.47G>C p.R16P | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV61481798; called by muse, mutect2
- CXCR5 | c.781G>T p.A261S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as rs1373094417, COSV52687543; called by muse, mutect2, varscan2
- DBN1 | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52791585; called by muse, mutect2, varscan2
- DDX53 | c.494A>G p.K165R | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV60069655; called by muse, mutect2, varscan2
- DDX59 | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV58753205; called by muse, mutect2, varscan2
- DEAF1 | c.1542G>T p.E514D | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58608511; called by muse, mutect2, varscan2
- DEGS1 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV60379815; called by muse, mutect2, varscan2
- DIPK2B | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as COSV65005667; called by muse, mutect2, varscan2
- DLG2 | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54670043; called by muse, mutect2, varscan2
- DMD | c.6151C>T p.R2051W | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs140791274, COSV100818956, COSV63777537; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH8 | c.12020T>A p.L4007* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as COSV59467794; called by muse, mutect2
- DOCK2 | c.2863T>A p.Y955N | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56975626; called by muse, mutect2, varscan2
- DOCK5 | c.3917C>T p.S1306L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV52407543; called by muse, mutect2, varscan2
- DOT1L | c.2211G>T p.Q737H | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.056); catalogued as COSV67112045; called by muse, mutect2, varscan2
- DROSHA | c.451A>G p.M151V | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs777764329, COSV60779885; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as COSV50052425; called by muse, mutect2, varscan2
- DYRK4 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV50542600, COSV50546700; called by muse, mutect2, varscan2
- EGR1 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV53520703; called by muse, mutect2, varscan2
- EIF4G1 | c.1022C>A p.S341Y (on ENST00000346169 / NM_198241.3; = p.S145Y on NM_004953.5) | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as COSV59992618; called by muse, mutect2
- EIF5 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53686303; called by muse, mutect2, varscan2
- ENTPD1 | c.238C>G p.Q80E | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.198); catalogued as COSV64600540, COSV64603365; called by muse, mutect2, varscan2
- EPHA10 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs267598587, COSV60404142; called by muse, mutect2, varscan2
- ERBIN | c.2761G>C p.D921H | Missense Mutation (SNP) | VAF 246/746 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52322986; called by muse, mutect2, varscan2
- ERC1 | c.1490C>T p.S497L (on ENST00000360905 / NM_178040.4; = p.S469L on NM_178039.4) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61695421; called by muse, mutect2, varscan2
- ERICH3 | c.2510G>A p.R837K | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as rs753189414, COSV58602882, COSV58613584; called by muse, mutect2, varscan2
- ERN1 | c.71G>A p.S24N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV70503733; called by muse, mutect2, varscan2
- EVI5L | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs865878229, COSV54487599; called by muse, mutect2
- EXOC1 | c.832-2A>G p.X278_splice | Splice Site (SNP) | VAF 12/63 reads (19%) | catalogued as COSV62121330; called by muse, mutect2, varscan2
- F8 | c.5344A>G p.I1782V | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as rs782149855, COSV64276831; called by muse, mutect2, varscan2
- F8 | c.5122del p.R1708Afs*23 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | catalogued as rs1209671783, CD1212743, CM1314171, CM880026; called by mutect2, pindel, varscan2
- FAAH2 | c.608T>A p.V203E | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV66510285; called by muse, mutect2, varscan2
- FAM135B | c.3755G>T p.G1252V | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52720445, COSV52742237; called by muse, mutect2, varscan2
- FAM227B | c.128A>T p.H43L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.037); catalogued as COSV54816036; called by muse, mutect2, varscan2
- FBXO42 | c.1689C>G p.I563M | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as COSV65045389; called by muse, mutect2, varscan2
- FCRL2 | c.930G>T p.Q310H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV63834508; called by muse, mutect2, varscan2
- FGFR2 | c.2357C>A p.T786K | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV60654751; called by muse, mutect2, varscan2
- FIGN | c.1597A>T p.T533S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.347); catalogued as COSV60769857; called by muse, mutect2, varscan2
- FLI1 | c.1285G>C p.G429R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV55643382, COSV55646658; called by muse, mutect2, varscan2
- FLNA | c.4259G>C p.G1420A | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61048380; called by muse, mutect2, varscan2
- FLNC | c.1709G>C p.G570A | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV57961051; called by muse, mutect2
- FREM2 | c.2698G>T p.V900F | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV54845772; called by muse, mutect2, varscan2
- FRG2B | c.65C>A p.P22H | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.865); catalogued as COSV71043589; called by muse, mutect2, varscan2
- FRMD7 | c.471G>C p.K157N | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53747949; called by muse, mutect2, varscan2
- GAL3ST2 | c.237C>A p.N79K | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV51951103; called by muse, mutect2, varscan2
- GATA1 | c.387C>A p.S129R | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV64962949, COSV64962985; called by muse, mutect2, varscan2
- GBF1 | c.550A>G p.T184A | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.553); catalogued as COSV64147461; called by muse, mutect2, varscan2
- GDPD4 | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60021404; called by muse, mutect2, varscan2
- GGN | c.1816C>A p.R606S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV53058085; called by muse, mutect2, varscan2
- GJB2 | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as CD054340, COSV67010791; called by muse, mutect2, varscan2
- GLG1 | c.2668-1G>C p.X890_splice | Splice Site (SNP) | VAF 29/114 reads (25%) | catalogued as COSV52671580; called by muse, mutect2, varscan2
- GON4L | c.5457G>C p.K1819N | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55199438; called by muse, mutect2, varscan2
- GON4L | c.2818G>C p.E940Q | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.432); catalogued as COSV55199455; called by muse, mutect2, varscan2
- GPR137B | c.300C>G p.F100L | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV63991071, COSV63991373; called by muse, mutect2, varscan2
- GPR171 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs151172001; called by muse, mutect2, varscan2
- H3-3A | c.168G>T p.Q56H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV64733394; called by muse, mutect2, varscan2
- HMCES | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67300707; called by muse, varscan2
- HORMAD2 | c.862T>C p.C288R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV60899859; called by muse, mutect2, varscan2
- HRNR | c.2093C>G p.S698C | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); catalogued as COSV64260977; called by muse, mutect2, varscan2
- HS6ST3 | c.1017G>C p.Q339H | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.852); catalogued as COSV100939890, COSV65013146, COSV65015211; called by muse, mutect2, varscan2
- ICAM1 | c.811T>C p.S271P | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.834); catalogued as COSV53426353; called by muse, mutect2, varscan2
- IFFO1 | c.1512G>T p.M504I (on ENST00000396840 / NM_001330324.2; = p.M507I on NM_080730.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV57521741; called by muse, mutect2, varscan2
- IFT43 | c.79C>G p.Q27E | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.107); catalogued as COSV53140290; called by muse, mutect2, varscan2
- IL12A | c.606+1G>C p.X202_splice | Splice Site (SNP) | VAF 12/244 reads (5%) | catalogued as COSV59759790; called by muse, mutect2
- IL17F | c.239C>A p.S80Y | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60234935; called by muse, mutect2, varscan2
- IL7R | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV57408492; called by muse, mutect2, varscan2
- INSR | c.3853G>A p.E1285K | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV57169226; called by muse, mutect2, varscan2
- IPP | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as COSV63433328; called by muse, mutect2, varscan2
- IRAK2 | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as rs748322441, COSV56534171; called by muse, mutect2, varscan2
- IRS1 | c.1381G>T p.E461* | Nonsense Mutation (SNP) | VAF 35/158 reads (22%) | catalogued as COSV59338595; called by muse, mutect2, varscan2
- ITGB1 | c.1958A>G p.N653S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.03); catalogued as COSV56484757; called by muse, mutect2, varscan2
- ITPRID2 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV57474794; called by muse, mutect2, varscan2
- JRKL | c.1390G>T p.E464* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV53594693; called by muse, mutect2, varscan2
- KALRN | c.3466A>C p.T1156P | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53774525; called by muse, mutect2, varscan2
- KANK2 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as rs768289917, COSV62009193; called by muse, mutect2, varscan2
- KANSL2 | c.663G>T p.K221N | Missense Mutation (SNP) | VAF 56/223 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV63480125; called by muse, mutect2, varscan2
- KAT8 | c.1321G>C p.V441L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54898227; called by muse, mutect2
- KIAA0319 | c.250C>A p.H84N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as rs1333977906, COSV65500863; called by muse, mutect2, varscan2
- KIAA0753 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as COSV63818247; called by muse, mutect2, varscan2
- KIF1A | c.1816C>G p.R606G | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); catalogued as COSV104412160, COSV57496340, COSV99064876; called by muse, mutect2, varscan2
- KIF5B | c.1616A>C p.K539T | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV56654715; called by muse, mutect2, varscan2
- KRT17 | c.1030G>T p.G344W | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60861537; called by muse, mutect2, varscan2
- KRT79 | c.316G>C p.G106R | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as COSV57941500; called by muse, mutect2, varscan2
- KRTAP24-1 | c.515C>G p.T172S | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61089882; called by muse, mutect2, varscan2
- LAMA2 | c.8704-1G>A p.X2902_splice | Splice Site (SNP) | VAF 17/77 reads (22%) | catalogued as COSV70351287; called by muse, mutect2, varscan2
- LEXM | c.773C>G p.P258R | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.915); catalogued as COSV64023639, COSV64024445; called by muse, mutect2, varscan2
- LILRA2 | c.353G>C p.G118A | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV52194819; called by muse, mutect2
- LPIN2 | c.2506G>C p.G836R | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54425948; called by muse, mutect2, varscan2
- LRFN5 | c.1443G>T p.M481I | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV53268426; called by muse, mutect2, varscan2
- LRRC32 | c.562A>T p.I188F | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52634532; called by muse, mutect2, varscan2
- LRRC4C | c.952G>T p.D318Y | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV53433104; called by muse, mutect2, varscan2
- LRRC8C | c.1509G>A p.M503I | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV64997747; called by muse, mutect2, varscan2
- MAGEE1 | c.1905G>T p.Q635H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV63911399; called by muse, mutect2, varscan2
- MASP1 | c.1788G>T p.R596S | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.013); catalogued as rs768987275, COSV61829246; called by muse, mutect2, varscan2
- MCTP1 | c.1021G>T p.G341C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56526959; called by muse, mutect2
- MGAM | c.2703G>T p.E901D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV72075109, COSV72075222; called by muse, mutect2, varscan2
- MID1 | c.955T>A p.S319T | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV58197475; called by muse, mutect2, varscan2
- MIIP | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as COSV52428322; called by muse, mutect2
- MMEL1 | c.2211G>C p.K737N | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.911); catalogued as COSV56524336; called by muse, mutect2, varscan2
- MPL | c.1670C>G p.S557* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV65246050; called by muse, mutect2, varscan2
- MSL3 | c.1057C>T p.R353C (on ENST00000312196 / NM_078629.4; = p.R187C on NM_006800.4) | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs780120545, COSV56491757, COSV56494938; called by muse, mutect2, varscan2
- MTERF1 | c.560G>C p.G187A | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61098850; called by muse, mutect2, varscan2
- MTTP | c.2063C>A p.S688Y | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV55508454; called by muse, mutect2, varscan2
- MTUS2 | c.530T>C p.L177S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV70919024; called by muse, mutect2, varscan2
- MXRA5 | c.1008C>G p.I336M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1330470215, COSV54243815; called by muse, mutect2, varscan2
- MYH15 | c.5494C>A p.R1832S | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV56309943, COSV56315876; called by muse, mutect2, varscan2
- MYH4 | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV55123192; called by muse, mutect2, varscan2
- MYO18A | c.1040A>C p.N347T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV62870928; called by muse, mutect2, varscan2
- NAA30 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV53649245; called by muse, mutect2, varscan2
- NECTIN4 | c.509C>G p.S170C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63513505; called by muse, mutect2, varscan2
- NHS | c.4574C>A p.P1525H | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV66279440; called by muse, mutect2
- NIBAN2 | c.971G>C p.R324P | Missense Mutation (SNP) | VAF 95/385 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64824016, COSV64825083; called by muse, mutect2, varscan2
- NLRP2 | c.1289T>G p.L430R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54752569, COSV54758352; called by mutect2, varscan2
- NOD2 | c.581G>C p.G194A | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.61); PolyPhen probably damaging (1); catalogued as COSV56049737, COSV56053426; called by muse, mutect2, varscan2
- NOTCH1 | c.6112G>T p.V2038L | Missense Mutation (SNP) | VAF 80/163 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV53045323; called by muse, mutect2, varscan2
- NOTUM | c.1481A>T p.N494I | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV68826422; called by muse, mutect2, varscan2
- NPAS4 | c.1135C>A p.P379T | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as COSV60651833; called by muse, mutect2, varscan2
- NPHS1 | c.3089A>T p.Q1030L | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV62289191; called by muse, mutect2, varscan2
- NSD1 | c.3161G>C p.R1054T | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as COSV61780763; called by muse, mutect2, varscan2
- NSRP1 | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.48); catalogued as COSV55934730; called by muse, mutect2, varscan2
- NUDCD3 | c.866A>T p.N289I | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV58126659; called by muse, mutect2, varscan2
- NUP133 | c.2999G>T p.R1000L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.165); catalogued as COSV54573927; called by muse, mutect2, varscan2
- NUP93 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 12/56 reads (21%) | catalogued as COSV57432593; called by muse, mutect2, varscan2
- OR14C36 | c.376C>A p.Q126K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV58602232; called by muse, mutect2, varscan2
- OR2T11 | c.54T>A p.S18R | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV58185506, COSV58186658; called by muse, mutect2, varscan2
- OR2T8 | c.223A>T p.T75S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV60663935; called by muse, mutect2, varscan2
- OR52M1 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV64172424; called by muse, mutect2, varscan2
- OR5B2 | c.729C>A p.F243L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV56909162; called by muse, mutect2
- OR5L2 | c.329C>G p.T110S | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as COSV65724667; called by muse, mutect2, varscan2
- OR6F1 | c.531C>G p.F177L | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57466785, COSV57467371, COSV57468804; called by muse, mutect2, varscan2
- P2RY1 | c.417C>G p.I139M | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59310076; called by muse, mutect2, varscan2
- P4HA3 | c.470G>C p.G157A | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59043074; called by muse, mutect2, varscan2
- P4HB | c.1357A>G p.T453A | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.033); catalogued as COSV58942401; called by muse, mutect2, varscan2
- PALB2 | c.1819C>G p.L607V | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV55168145, COSV99847989; called by mutect2, varscan2
- PAX4 | c.706C>G p.Q236E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.46); catalogued as rs1328872875, COSV58390206; called by muse, mutect2, varscan2
- PCDHB16 | c.814G>T p.G272* | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | catalogued as rs1318451722, COSV53367591; called by muse, mutect2, varscan2
- PCDHB16 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53367598, COSV99501893; called by muse, mutect2, varscan2
- PCLO | c.7045G>T p.A2349S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as COSV61653532; called by muse, mutect2, varscan2
- PCSK7 | c.678C>A p.N226K | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58008777; called by muse, mutect2, varscan2
- PDE6C | c.1591G>C p.E531Q | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.959); catalogued as COSV101008679, COSV65116943; called by muse, mutect2, varscan2
- PDE6H | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as COSV56760417, COSV99844047; called by muse, mutect2
- PDE6H | c.56C>G p.P19R | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.999); catalogued as COSV56760431, COSV56761483; called by muse, mutect2, varscan2
- PGM5 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | catalogued as COSV67164659; called by muse, mutect2, varscan2
- PHLDB3 | c.1094A>G p.H365R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.61); catalogued as COSV52671115; called by mutect2, varscan2
- PLCL1 | c.1168G>C p.D390H | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV70835107, COSV70854336; called by muse, mutect2, varscan2
- PLXNB2 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV63783473; called by muse, mutect2
- PNKP | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1391995905, COSV55589394; called by muse, mutect2, varscan2
- PNMA3 | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64722728; called by muse, mutect2, varscan2
- POTEE | c.2732A>G p.D911G | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV58238466; called by muse, mutect2, varscan2
- POTEF | c.101G>T p.C34F | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.308); catalogued as COSV62542857; called by muse, mutect2, varscan2
- PRICKLE3 | c.1625C>T p.S542L | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.052); catalogued as rs192584914, COSV66235274; called by muse, mutect2, varscan2
- PRKG2 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV52329063; called by muse, varscan2
- PRMT7 | c.1948T>A p.Y650N | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV54714323; called by muse, mutect2, varscan2
- PRR23B | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV61494494; called by muse, mutect2, varscan2
- PTPRD | c.5704G>C p.E1902Q | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs139384612, COSV61935401; called by muse, mutect2, varscan2
- PZP | c.3278T>C p.L1093P | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54366416; called by muse, mutect2, varscan2
- RALGAPA2 | c.5503G>A p.E1835K | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52504971; called by muse, mutect2, varscan2
- REG3A | c.398G>T p.W133L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59410776; called by muse, mutect2, varscan2
- RGS7 | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58552942; called by muse, mutect2, varscan2
- RNASE10 | c.58G>T p.G20W | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV60518058; called by muse, mutect2, varscan2
- RNF186 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 23/93 reads (25%) | catalogued as COSV64296870, COSV64296876; called by muse, mutect2, varscan2
- RXFP2 | c.1096C>A p.P366T | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV53635383, COSV53638534; called by muse, mutect2, varscan2
- SATL1 | c.649T>A p.S217T (on ENST00000395409; = p.S404T on NM_001012980.2) | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.19); catalogued as COSV60577812; called by muse, varscan2
- SCAMP2 | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51512741; called by muse, mutect2
- SCN2A | c.2354A>C p.E785A | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV51850071; called by muse, mutect2
- SCN9A | c.1746G>C p.E582D | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.057); catalogued as rs755931870, COSV100314601, COSV57618237; called by muse, mutect2, varscan2
- SCYL2 | c.1981G>C p.E661Q | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.088); catalogued as COSV62570007; called by muse, mutect2, varscan2
- SELPLG | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as COSV57313967; called by muse, mutect2, varscan2
- SEMA5A | c.1703G>T p.R568L | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66801157; called by muse, mutect2, varscan2
- SFN | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as COSV59433782; called by muse, mutect2
- SHROOM2 | c.2623G>A p.E875K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66609258; called by muse, mutect2, varscan2
- SIDT1 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs990449684, COSV53504467; called by muse, mutect2, varscan2
- SIGLEC1 | c.2918C>T p.A973V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52468968; called by muse, mutect2, varscan2
- SIRPD | c.218A>T p.K73I | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV67547036; called by muse, mutect2, varscan2
- SIRPG | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53809007; called by muse, mutect2, varscan2
- SLA | c.397del p.R133Afs*25 (on ENST00000338087 / NM_001045556.3; = p.R173Afs*25 on NM_006748.4) | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as COSV55065091; called by mutect2, pindel, varscan2
- SLC14A2 | c.2752G>A p.D918N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.454); catalogued as rs368161253, COSV54908027; called by muse, mutect2, varscan2
- SLC17A8 | c.167A>T p.Q56L | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV60125490; called by muse, mutect2, varscan2
- SLC17A8 | c.1662T>A p.N554K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.065); catalogued as COSV60125499; called by muse, mutect2
- SLC35E4 | c.970C>G p.L324V | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.26); catalogued as COSV55899491; called by muse, mutect2, varscan2
- SLC3A1 | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53224052; called by muse, mutect2, varscan2
- SLC6A13 | c.761C>G p.T254R | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58258894; called by muse, mutect2, varscan2
- SLC8A2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV52641670; called by muse, mutect2, varscan2
- SLC9C1 | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs142600000, COSV59889831; called by muse, mutect2, varscan2
- SLCO1B1 | c.364A>T p.R122W | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57014570; called by muse, mutect2, varscan2
- SLITRK4 | c.1143G>T p.K381N | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62024329, COSV62025392; called by muse, mutect2, varscan2
- SOS1 | c.2896G>C p.E966Q | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV67676732; called by muse, mutect2, varscan2
- SPHKAP | c.2624C>A p.A875D | Missense Mutation (SNP) | VAF 165/844 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV60889026; called by muse, mutect2, varscan2
- SPHKAP | c.1039T>A p.S347T | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV60872502; called by muse, mutect2, varscan2
- SPICE1 | c.1219C>T p.H407Y | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55622397, COSV55623402, COSV99871814; called by muse, mutect2, varscan2
- SPIN4 | c.25A>C p.M9L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV58738351; called by muse, mutect2, varscan2
- STAG2 | c.3385C>T p.P1129S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV54367048; called by muse, mutect2, varscan2
- STAP2 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV74075482; called by muse, mutect2, varscan2
- SYMPK | c.2033C>T p.A678V | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV55614147; called by muse, mutect2, varscan2
- SYNE3 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV62081236; called by muse, mutect2, varscan2
- SYT16 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV70855209, COSV70858311; called by muse, mutect2, varscan2
- SYTL4 | c.200A>G p.Q67R | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as COSV52169956; called by muse, mutect2, varscan2
- SZT2 | c.3017A>G p.Q1006R | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV65172454; called by muse, mutect2, varscan2
- TAF1 | c.1894C>G p.Q632E (on ENST00000373790 / NM_138923.4; = p.Q653E on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.796); catalogued as COSV52120779; called by muse, mutect2, varscan2
- TAF1 | c.3777C>G p.C1259W (on ENST00000373790 / NM_138923.4; = p.C1280W on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52120806; called by muse, mutect2, varscan2
- TAS2R39 | c.377G>T p.W126L | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71470961; called by muse, mutect2, varscan2
- TMC6 | c.1611G>T p.Q537H | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as rs1235726127, COSV59810347; called by muse, mutect2, varscan2
- TMEM106A | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV57834417; called by muse, mutect2, varscan2
- TMPO | c.1081G>T p.A361S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58463001; called by muse, varscan2
- TMTC1 | c.2008G>A p.E670K (on ENST00000539277 / NM_001193451.2; = p.E562K on NM_175861.3) | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55488695; called by muse, mutect2, varscan2
- TNN | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53428493; called by muse, mutect2, varscan2
- TNPO2 | c.2174C>T p.A725V | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV63509400; called by muse, mutect2, varscan2
- TNRC6B | c.117G>A p.V39= | Splice Region (SNP) | VAF 10/48 reads (21%) | catalogued as COSV57302988; called by muse, mutect2, varscan2
- TRA2B | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.18); catalogued as COSV52026052; called by muse, mutect2, varscan2
- TRIOBP | c.6809G>T p.G2270V (on ENST00000644935 / NM_001039141.3; = p.G557V on NM_007032.5) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.617); catalogued as COSV60381734; called by muse, mutect2, varscan2
- TRIP12 | c.3681C>G p.S1227R | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52269498; called by muse, mutect2, varscan2
- TRPM2 | c.2785C>T p.R929W | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1408663909, COSV55966822, COSV55968923; called by muse, mutect2, varscan2
- TSHZ3 | c.2753C>T p.S918L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as rs199819394, COSV53677947; called by muse, varscan2
- TTN | c.87145T>A p.Y29049N (on ENST00000591111; = p.Y21625N on NM_003319.4) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | PolyPhen probably damaging (0.998); catalogued as COSV60225305; called by muse, mutect2, varscan2
- UBR5 | c.4919G>C p.R1640T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV55295062; called by muse, mutect2, varscan2
- UGGT2 | c.870C>G p.F290L | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.9); PolyPhen benign (0.013); catalogued as COSV65025781; called by muse, mutect2, varscan2
- UGT2A1 | c.926C>A p.S309* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as COSV54144836; called by muse, mutect2, varscan2
- ULBP1 | c.635C>G p.S212C | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV57664713; called by muse, mutect2, varscan2
- UNC79 | c.6848T>G p.L2283R (on ENST00000393151 / NM_001346218.2; = p.L2106R on NM_020818.5) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV56401192; called by muse, mutect2, varscan2
- USP11 | c.1403G>T p.C468F (on ENST00000218348; = p.C425F on NM_001371072.1) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54475124; called by muse, mutect2, varscan2
- USP37 | c.1693C>T p.R565* | Nonsense Mutation (SNP) | VAF 21/97 reads (22%) | catalogued as COSV51445776; called by muse, mutect2, varscan2
- USP54 | c.3064C>G p.Q1022E | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.039); catalogued as COSV60440300; called by muse, mutect2, varscan2
- UTP14A | c.2128C>T p.Q710* | Nonsense Mutation (SNP) | VAF 22/90 reads (24%) | catalogued as COSV64087523; called by muse, mutect2, varscan2
- VCAN | c.8589T>G p.D2863E | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV54112161; called by muse, mutect2, varscan2
- VEGFD | c.928G>C p.D310H | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV52910479; called by muse, mutect2, varscan2
- VIM | c.45C>A p.F15L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56406979; called by muse, mutect2, varscan2
- VPS13B | c.1259C>G p.S420C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV62023407; called by muse, mutect2, varscan2
- VPS13D | c.447+1G>A p.X149_splice | Splice Site (SNP) | VAF 12/47 reads (26%) | catalogued as COSV62532612; called by muse, mutect2, varscan2
- VTA1 | c.379G>T p.V127F | Missense Mutation (SNP) | VAF 76/146 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62659895; called by muse, mutect2, varscan2
- WASHC5 | c.1194G>C p.Q398H | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.991); catalogued as COSV59199024; called by muse, mutect2
- WASHC5 | c.1027C>G p.Q343E | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.926); catalogued as COSV59199034; called by muse, mutect2, varscan2
- WDR17 | c.3135G>T p.M1045I | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.19); catalogued as COSV54579472; called by muse, mutect2, varscan2
- WSCD1 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); catalogued as rs370044604, COSV58497025; called by muse, mutect2, varscan2
- XIRP2 | c.6847A>C p.T2283P (on ENST00000628543; = p.T2458P on NM_152381.6) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.77); catalogued as COSV54720794, COSV99739603; called by muse, mutect2, varscan2
- ZBTB11 | c.2101C>T p.H701Y | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57246222; called by muse, mutect2, varscan2
- ZBTB40 | c.452C>G p.S151C | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as rs369096143, COSV65146093; called by muse, mutect2, varscan2
- ZDHHC15 | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64902855, COSV64902934; called by muse, varscan2
- ZFP3 | c.1432G>C p.E478Q | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.492); catalogued as COSV59583586; called by muse, mutect2, varscan2
- ZFYVE1 | c.829T>C p.F277L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV59612177; called by muse, mutect2, varscan2
- ZFYVE28 | c.2237C>A p.A746D | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV52115000; called by muse, mutect2, varscan2
- ZNF208 | c.2649T>G p.H883Q | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV68107815, COSV68110399; called by muse, mutect2, varscan2
- ZNF416 | c.437A>C p.E146A | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV52185281, COSV99544021; called by muse, mutect2, varscan2
- ZNF470 | c.1780G>T p.E594* | Nonsense Mutation (SNP) | VAF 17/87 reads (20%) | catalogued as COSV57970068; called by muse, mutect2, varscan2
- ZNF664 | c.44G>T p.R15I | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV61878366; called by muse, mutect2, varscan2
- CSMD2 | c.1327-5_1338del p.X443_splice | Splice Site (DEL) | VAF 13/72 reads (18%) | called by mutect2, pindel, varscan2
- DOCK11 | c.1633_1653del p.D545_L551del | In Frame Del (DEL) | VAF 26/127 reads (20%) | called by mutect2, pindel, varscan2
- GAS2L2 | c.1880C>A p.S627Y | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- HCN2 | c.1510del p.Y504Mfs*54 | Frame Shift Del (DEL) | VAF 38/164 reads (23%) | called by mutect2, pindel, varscan2
- HDAC4 | c.3084_3093del p.W1028Cfs*12 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel
- HSPA4L | c.919_940del p.E307Wfs*8 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- JAK2 | c.168del p.P58Hfs*30 | Frame Shift Del (DEL) | VAF 12/95 reads (13%) | called by mutect2, pindel, varscan2
- KIR2DL1 | c.777_791del p.L260_L264del | In Frame Del (DEL) | VAF 24/147 reads (16%) | called by mutect2, pindel
- MAGEF1 | c.223del p.R75Gfs*2 | Frame Shift Del (DEL) | VAF 79/212 reads (37%) | called by mutect2, pindel, varscan2
- MUC5B | c.11016del p.S3673Afs*24 | Frame Shift Del (DEL) | VAF 19/69 reads (28%) | called by mutect2, varscan2
- ODAPH | c.10_19del p.R4Sfs*12 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- PCDHGB5 | c.1646del p.G549Afs*36 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | called by mutect2, pindel*, varscan2
- SLC18A2 | c.741_744del p.K248Rfs*37 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | called by mutect2, pindel, varscan2
- SPHKAP | c.2309_2319del p.S770Tfs*2 | Frame Shift Del (DEL) | VAF 41/249 reads (16%) | called by mutect2, pindel, varscan2
- TGFB2 | c.566_570delinsC p.V189Afs*14 | Frame Shift Del (DEL) | VAF 29/166 reads (17%) | called by pindel, varscan2*
- TRAV8-1 | c.266G>A p.S89N | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TRGV3 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 25/113 reads (22%) | called by muse, mutect2, varscan2
- VSIG4 | c.1012A>C p.I338L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- WASHC2A | c.3373G>T p.G1125W | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- XKR3 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- ZNF77 | c.434_445del p.T145_G148del | In Frame Del (DEL) | VAF 19/141 reads (13%) | called by mutect2, pindel, varscan2
- ABCC6 | c.1872C>T p.A624= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs747341864, COSV52746489; called by muse, mutect2
- ACSM2B | c.1386A>C p.A462= | Silent (SNP) | VAF 46/310 reads (15%) | catalogued as rs1303815292, COSV61659155; called by muse, mutect2, varscan2
- ADAM7 | c.9C>T p.P3= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as rs1178281383, COSV51543940; called by muse, mutect2, varscan2
- ADAMTS16 | c.471C>G p.S157= | Silent (SNP) | VAF 23/190 reads (12%) | catalogued as COSV57000064; called by muse, mutect2, varscan2
- ADD2 | c.114G>T p.A38= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV52466809; called by muse, mutect2, varscan2
- ADGRG2 | c.1647A>G p.T549= (on ENST00000379869 / NM_001079858.3; = p.T546= on NM_005756.4) | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs1368372714, COSV61340448; called by muse, mutect2, varscan2
- ALG14 | c.640C>A p.R214= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV100930835, COSV64635505; called by muse, mutect2, varscan2
- ATP2B1 | c.3333G>C p.L1111= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as COSV53810795; called by muse, mutect2, varscan2
- BDKRB2 | c.117C>T p.N39= | Silent (SNP) | VAF 57/259 reads (22%) | catalogued as rs201661317, COSV60014201; called by muse, mutect2, varscan2
- C1GALT1C1 | c.732T>C p.D244= | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as COSV58974554; called by muse, mutect2, varscan2
- CABS1 | c.852T>A p.T284= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV56734189; called by muse, mutect2, varscan2
- CAMK1G | c.1110G>A p.L370= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV50524244; called by muse, mutect2, varscan2
- CARMIL2 | c.1935C>T p.D645= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV58029856; called by muse, mutect2, varscan2
- CD72 | c.585G>T p.T195= | Silent (SNP) | VAF 42/132 reads (32%) | catalogued as COSV52411937; called by muse, mutect2, varscan2
- CDH12 | c.585T>C p.S195= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV66428983; called by muse, mutect2, varscan2
- CDH9 | c.1554C>A p.P518= | Silent (SNP) | VAF 29/210 reads (14%) | catalogued as COSV50252345, COSV50362557; called by muse, mutect2, varscan2
- DCAF1 | c.3777T>C p.N1259= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV60040420; called by muse, mutect2, varscan2
- DISP3 | c.1788C>T p.L596= | Silent (SNP) | VAF 32/117 reads (27%) | catalogued as rs376122183; called by muse, mutect2, varscan2
- EYA4 | c.540C>A p.A180= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as COSV62057822; called by mutect2, varscan2
- FAH | c.933G>T p.A311= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV55722856; called by muse, mutect2, varscan2
- FAM47A | c.222C>T p.D74= | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as COSV60495771; called by muse, mutect2, varscan2
- FGF13 | c.735G>C p.T245= | Silent (SNP) | VAF 48/191 reads (25%) | catalogued as COSV59545789, COSV59548717; called by muse, mutect2, varscan2
- FLG2 | c.1362C>A p.G454= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as COSV66171175; called by muse, mutect2, varscan2
- FLNA | c.843G>T p.P281= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV61048392; called by muse, mutect2, varscan2
- FREM1 | c.4101C>T p.F1367= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV66527308; called by muse, mutect2, varscan2
- GLB1L | c.1032G>A p.K344= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV55477949; called by muse, mutect2, varscan2
- GPR173 | c.177C>T p.Y59= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV60237454; called by muse, mutect2, varscan2
- GRM6 | c.2256C>A p.I752= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs376987111, COSV51447241; called by muse, mutect2, varscan2
- HERC6 | c.2424G>A p.L808= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV52032836; called by muse, mutect2, varscan2
- HTRA1 | c.1035G>A p.L345= | Silent (SNP) | VAF 39/157 reads (25%) | catalogued as COSV64564888; called by muse, mutect2, varscan2
- IGFL3 | c.336C>T p.S112= | Silent (SNP) | VAF 53/234 reads (23%) | catalogued as COSV58243140; called by muse, mutect2, varscan2
- IGSF11 | c.106C>A p.R36= (on ENST00000393775 / NM_001015887.3; = p.R35= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV61169579, COSV61174748; called by muse, mutect2, varscan2
- INTS10 | c.378A>G p.L126= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs751720146, COSV67604710; called by muse, mutect2, varscan2
- ITIH6 | c.2724C>A p.I908= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV54492172; called by muse, mutect2, varscan2
- JADE3 | c.390G>A p.E130= | Silent (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- KIAA0319L | c.2583G>T p.A861= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV57848640; called by muse, mutect2, varscan2
- KPNA4 | c.1566G>A p.*522= | Silent (SNP) | VAF 26/204 reads (13%) | catalogued as COSV62076532; called by muse, varscan2
- KRT13 | c.984C>A p.L328= | Silent (SNP) | VAF 40/145 reads (28%) | catalogued as COSV55840920; called by muse, mutect2, varscan2
- LAS1L | c.1893A>T p.G631= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV56708427; called by muse, mutect2, varscan2
- MAP7D3 | c.1698T>A p.S566= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as COSV60171935; called by muse, mutect2, varscan2
- NEU1 | c.828C>T p.V276= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV57668519; called by muse, mutect2, varscan2
- NHS | c.4575C>A p.P1525= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV66279450; called by muse, mutect2
- OPRL1 | c.114C>G p.L38= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs776074996, COSV61092432; called by muse, mutect2, varscan2
- OR10AG1 | c.597G>A p.T199= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs750193037, COSV56631361; called by muse, mutect2, varscan2
- OR10Z1 | c.246C>A p.L82= | Silent (SNP) | VAF 46/230 reads (20%) | catalogued as COSV100779060, COSV63525853; called by muse, mutect2, varscan2
- OR2M4 | c.642C>A p.I214= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV60709116, COSV60709665; called by muse, mutect2, varscan2
- OSBPL2 | c.717C>A p.V239= (on ENST00000313733 / NM_144498.4; = p.V227= on NM_014835.4) | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as COSV58218649; called by muse, mutect2, varscan2
- PASD1 | c.687T>A p.A229= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as COSV64856712; called by muse, mutect2, varscan2
- PCDH10 | c.2326C>A p.R776= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV52100013; called by muse, varscan2
- PGR | c.2475A>G p.L825= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV54797054; called by muse, mutect2, varscan2
- PLA2G4A | c.471C>T p.F157= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as COSV66555487; called by muse, mutect2, varscan2
- PREX1 | c.4320C>T p.I1440= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV64254831; called by muse, mutect2, varscan2
- PROS1 | c.1404A>G p.Q468= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV67775707, COSV67776501; called by muse, mutect2, varscan2
- RAB21 | c.375C>T p.I125= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV54229626; called by muse, mutect2, varscan2
- RAB9A | c.213C>T p.S71= | Silent (SNP) | VAF 50/230 reads (22%) | catalogued as COSV54611104; called by muse, mutect2, varscan2
- RADIL | c.2968C>T p.L990= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs747460408, COSV68202613; called by muse, mutect2, varscan2
- RGS7 | c.531G>T p.V177= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV58552959; called by muse, mutect2, varscan2
- RNASE8 | c.369G>A p.K123= | Silent (SNP) | VAF 80/168 reads (48%) | catalogued as COSV57551799; called by muse, mutect2, varscan2
- RPL8 | c.762G>A p.E254= | Silent (SNP) | VAF 46/280 reads (16%) | catalogued as COSV52799669; called by muse, mutect2, varscan2
- RUNX2 | c.957C>A p.T319= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV61839407, COSV61844103; called by muse, mutect2, varscan2
- SAMD4B | c.795C>G p.P265= | Silent (SNP) | VAF 17/140 reads (12%) | catalogued as rs891788884, COSV58752666; called by muse, mutect2, varscan2
- SCN2A | c.2352G>A p.T784= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as rs369101059, COSV51850051; ClinVar: likely benign; called by muse, mutect2
- SERPINA10 | c.1014G>A p.P338= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs140430900; called by muse, mutect2, varscan2
- SF3B2 | c.1473C>G p.L491= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV59429417; called by muse, mutect2, varscan2
- SGCG | c.843C>T p.T281= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs1566049936, COSV54565027; called by muse, mutect2, varscan2
- SLITRK3 | c.327G>A p.G109= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV53851376; called by muse, mutect2, varscan2
- SOCS4 | c.798G>T p.T266= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV59461265; called by muse, mutect2, varscan2
- SOGA3 | c.1977G>T p.L659= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV64107913; called by muse, mutect2, varscan2
- SPAG5 | c.2943G>A p.Q981= | Silent (SNP) | VAF 42/139 reads (30%) | catalogued as rs765754784, COSV56887053; called by muse, mutect2, varscan2
- SPEG | c.5382C>T p.I1794= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV56676076; called by muse, mutect2, varscan2
- SYMPK | c.3699G>A p.A1233= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV55574018; called by muse, mutect2
- TAF9B | c.261C>A p.P87= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV59372004, COSV59372325; called by muse, mutect2, varscan2
- TANC2 | c.2226G>A p.Q742= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs1052814092, COSV67338571; called by muse, mutect2, varscan2
- TBX3 | c.213G>A p.A71= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV57474063; called by muse, varscan2
- TBX3 | c.144C>A p.P48= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV57474072; called by muse, varscan2
- TENM1 | c.5304C>G p.L1768= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as COSV64438545; called by muse, mutect2, varscan2
- TIE1 | c.3180C>T p.A1060= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs775620996, COSV65250710; called by muse, mutect2, varscan2
- TM4SF20 | c.42C>T p.S14= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV58819225; called by muse, mutect2, varscan2
- TTI1 | c.2994C>T p.D998= | Silent (SNP) | VAF 29/129 reads (22%) | catalogued as rs764898421, COSV65062684; called by muse, mutect2, varscan2
- UNC13C | c.4866C>T p.N1622= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV52904052; called by muse, mutect2, varscan2
- UNC79 | c.2286T>C p.S762= (on ENST00000393151 / NM_001346218.2; = p.S585= on NM_020818.5) | Silent (SNP) | VAF 54/246 reads (22%) | catalogued as COSV56401169; called by muse, mutect2, varscan2
- WDFY3 | c.870C>T p.L290= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV55709459; called by muse, mutect2, varscan2
- WDR44 | c.1446A>G p.P482= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as rs1569372555, COSV54166458; called by muse, mutect2, varscan2
- WDR72 | c.360G>T p.R120= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV64751159, COSV64752858; called by muse, mutect2, varscan2
- ZDBF2 | c.54G>T p.L18= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV65628519; called by muse, mutect2, varscan2
- ZDHHC19 | c.192C>T p.I64= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV56349548, COSV99579823; called by muse, mutect2, varscan2
- ZNF181 | c.624A>G p.K208= | Silent (SNP) | VAF 11/106 reads (10%) | catalogued as COSV67627071; called by muse, mutect2, varscan2
- ZNF496 | c.1365G>A p.E455= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs769986993, COSV54180315; called by muse, mutect2, varscan2
- ZNF585B | c.2037A>C p.T679= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs755462793; called by muse, mutect2, varscan2
- ZSCAN25 | c.1062G>T p.G354= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV53553946; called by muse, mutect2, varscan2
- ZXDB | c.177C>T p.R59= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV66493237; called by muse, mutect2
- AC024940.1 | n.5105G>T | RNA (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- AC073310.1 | n.375C>A | RNA (SNP) | VAF 39/153 reads (25%) | catalogued as rs371902318; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846180 G>T | 5'Flank (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2, varscan2
- ANKS1B | c.3067-6742T>G | Intron (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- CRYM-AS1 | n.337C>T | RNA (SNP) | VAF 34/149 reads (23%) | called by muse, mutect2, varscan2
- DUXA | c.-1C>A | 5'UTR (SNP) | VAF 24/111 reads (22%) | called by muse, mutect2, varscan2
- MYB | c.1203+996T>G | Intron (SNP) | VAF 49/100 reads (49%) | called by muse, mutect2, varscan2
- PRND | chr20:4732436 C>G | 3'Flank (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- SLC22A17 | n.1549C>T | RNA (SNP) | VAF 16/34 reads (47%) | catalogued as COSV52836625; called by muse, mutect2, varscan2
- SNORD116-11 | n.62T>G | RNA (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- SPATA8 | n.717A>C | RNA (SNP) | VAF 13/44 reads (30%) | catalogued as COSV60705297; called by muse, mutect2, varscan2
- TMEM107 | c.*676T>G | 3'UTR (SNP) | VAF 8/32 reads (25%) | catalogued as rs761878851, COSV100328841; called by muse, mutect2, varscan2
- TRO | c.*96C>A | 3'UTR (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- TRO | c.*97C>A | 3'UTR (SNP) | VAF 19/95 reads (20%) | catalogued as COSV99435533; called by muse, mutect2, varscan2
- TTN | c.10360+4421C>A | Intron (SNP) | VAF 25/109 reads (23%) | catalogued as COSV60225351; called by muse, mutect2, varscan2
